Somatic mutation profile of tumor specimen TCGA-33-AASI-01A (aliquot TCGA-33-AASI-01A-22D-A401-08) from TCGA case TCGA-33-AASI, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 65.6 years (23,965 days).
Specimen TCGA-33-AASI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7d2ee76-e53a-41d5-ad1b-318316605503.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-33-AASI-11A (Solid Tissue Normal), aliquot TCGA-33-AASI-11A-11D-A401-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2284dc0d-26f5-47ad-8795-fc0e6a52fc39

The open-access MAF lists 451 somatic variants for this specimen: 344 protein-altering or splice-affecting, 92 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 296, Silent 92, Nonsense Mutation 26, Splice Site 10, Frame Shift Del 6, RNA 6, Intron 4, Frame Shift Ins 3, 3'UTR 2, Splice Region 2, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.1466A>G p.Y489C | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs137854557, CM1111787, CS992455, COSV62194445; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RASA1 | c.2707C>T p.R903* | Nonsense Mutation (SNP) | VAF 20/45 reads (44%) | catalogued as rs1554050230, CM1311713, COSV57192847; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 48/89 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AADACL3 | c.701C>A p.S234* | Nonsense Mutation (SNP) | VAF 43/258 reads (17%) | catalogued as COSV100206713, COSV60200198; called by muse, mutect2, varscan2
- ABCA8 | c.4493A>G p.Q1498R | Missense Mutation (SNP) | VAF 46/74 reads (62%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV99285793; called by muse, mutect2, varscan2
- ABRA | c.859G>C p.G287R | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100357573; called by muse, mutect2, varscan2
- ACAN | c.882G>T p.M294I | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV100718121; called by muse, mutect2, varscan2
- ACAN | c.2395C>A p.P799T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.117); catalogued as rs1282326768, COSV100718122; called by muse, mutect2, varscan2
- ACIN1 | c.1165C>T p.P389S | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.328); catalogued as COSV99399434; called by muse, mutect2, varscan2
- ACTG2 | c.592G>T p.G198C | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.336); catalogued as rs1412192979, COSV100609196; called by muse, mutect2, varscan2
- ACVR1B | c.678G>T p.W226C | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99231499; called by muse, mutect2, varscan2
- ADAT1 | c.32G>T p.C11F | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100329220; called by muse, mutect2, varscan2
- ADGRA1 | c.64C>T p.H22Y | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.607); catalogued as COSV101658606; called by muse, mutect2, varscan2
- ADGRL4 | c.1417G>T p.A473S | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV100875960; called by muse, mutect2, varscan2
- ADGRV1 | c.12803G>A p.R4268Q | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1326096741, COSV67985018; called by muse, mutect2, varscan2
- AHNAK2 | c.11215C>A p.P3739T | Missense Mutation (SNP) | VAF 70/413 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100317536; called by mutect2, varscan2
- AHR | c.2173G>A p.E725K | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.219); catalogued as COSV99619720; called by muse, mutect2, varscan2
- AJUBA | c.255C>G p.Y85* | Nonsense Mutation (SNP) | VAF 6/17 reads (35%) | catalogued as rs949447270, COSV99400993; called by muse, mutect2, varscan2
- ALKBH2 | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.277); catalogued as COSV99980383; called by muse, mutect2, varscan2
- ALKBH2 | c.59A>G p.Q20R | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV99655354; called by muse, mutect2, varscan2
- ANK3 | c.9457C>G p.L3153V | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99780031; called by muse, mutect2, varscan2
- ANKRD30A | c.1009G>A p.D337N (on ENST00000611781; = p.D281N on NM_052997.2) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.099); catalogued as COSV100653549; called by muse, mutect2, varscan2
- ANKRD30A | c.1748C>A p.P583H (on ENST00000611781; = p.P527H on NM_052997.2) | Missense Mutation (SNP) | VAF 37/239 reads (15%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.99); catalogued as COSV100653551; called by muse, mutect2, varscan2
- ANKRD44 | c.1304A>G p.D435G | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56551283, COSV99985007; called by muse, mutect2, varscan2
- ANO1 | c.1560G>T p.L520F | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs767000418, COSV100304016; called by muse, mutect2, varscan2
- APLP2 | c.220C>G p.P74A | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.657); catalogued as COSV99599712; called by muse, mutect2, varscan2
- ARHGEF18 | c.3160G>C p.G1054R (on ENST00000359920 / NM_001130955.2; = p.G950R on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV100149524, COSV60469136; called by muse, mutect2, varscan2
- ARHGEF40 | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as rs1248979744, COSV53878904; called by muse, mutect2, varscan2
- ARMC4 | c.1747G>T p.A583S | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV100536843; called by muse, mutect2, varscan2
- ASAP2 | c.489G>T p.E163D | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99856216; called by muse, mutect2, varscan2
- ASB15 | c.1348C>A p.H450N | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV51929462, COSV99306536; called by muse, mutect2, varscan2
- ASB15 | c.1349A>T p.H450L | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV99306538; called by muse, mutect2, varscan2
- ASTN1 | c.2051G>T p.C684F | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1456798991, COSV99921696; called by muse, mutect2, varscan2
- ATM | c.8645C>G p.S2882* | Nonsense Mutation (SNP) | VAF 19/84 reads (23%) | catalogued as COSV99589645, COSV99590512; called by muse, mutect2, varscan2
- ATP6V1C1 | c.866A>T p.E289V | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101214990; called by muse, mutect2, varscan2
- ATRX | c.2565C>A p.H855Q | Missense Mutation (SNP) | VAF 78/233 reads (33%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); catalogued as COSV100970793; called by muse, mutect2, varscan2
- BMP6 | c.1021C>A p.P341T | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as COSV99306976; called by muse, mutect2, varscan2
- BPTF | c.5779C>G p.P1927A | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.437); catalogued as COSV100074996, COSV58841115; called by muse, mutect2, varscan2
- BRINP2 | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.003); catalogued as rs756669472, COSV64181399; called by muse, mutect2, varscan2
- BRSK1 | c.2066C>T p.S689F | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100474099; called by muse, mutect2, varscan2
- BTN2A2 | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs775875965, COSV61857154; called by muse, mutect2, varscan2
- C6 | c.2249C>A p.S750Y | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54705755, COSV99667107; called by muse, mutect2, varscan2
- CAB39L | c.370C>G p.H124D | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV100759559, COSV104418358; called by muse, mutect2
- CABP2 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs963261198, COSV53708354; called by muse, mutect2, varscan2
- CACNA1D | c.92G>T p.R31I | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99858209; called by muse, mutect2, varscan2
- CACNA1E | c.5866G>T p.D1956Y | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as COSV100701833, COSV100702676; called by muse, mutect2, varscan2
- CACNA1S | c.3607G>T p.D1203Y | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100755012; called by muse, mutect2, varscan2
- CAPSL | c.173C>A p.T58N | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV101274266; called by muse, mutect2, varscan2
- CBLL1 | c.1362G>C p.W454C | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV56029804, COSV99755666; called by muse, mutect2, varscan2
- CCDC115 | c.479G>A p.W160* | Nonsense Mutation (SNP) | VAF 15/50 reads (30%) | catalogued as COSV99383729, COSV99383892; called by muse, mutect2, varscan2
- CCDC181 | c.98G>C p.S33T | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.085); catalogued as COSV100890318; called by muse, mutect2, varscan2
- CCDC62 | c.391C>G p.L131V | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99457143, COSV99457740; called by muse, mutect2, varscan2
- CCDC85A | c.360G>C p.K120N | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1313394301, COSV101339466, COSV68147637; called by muse, mutect2, varscan2
- CDC42BPB | c.2058C>G p.I686M | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100775454, COSV63475969; called by muse, mutect2, varscan2
- CDH6 | c.1778A>G p.H593R | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV99419216; called by muse, mutect2, varscan2
- CDH8 | c.997C>G p.Q333E | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as rs1284030303, COSV100181590; called by muse, mutect2, varscan2
- CDHR2 | c.1118C>T p.T373I | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV99991621; called by muse, mutect2, varscan2
- CEMIP | c.3699+1G>A p.X1233_splice | Splice Site (SNP) | VAF 21/68 reads (31%) | catalogued as COSV99586744; called by muse, mutect2, varscan2
- CEP95 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as COSV73609715; called by mutect2, varscan2
- CHMP2A | c.466G>C p.D156H | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs749084452, COSV99448157; called by muse, mutect2, varscan2
- CLDN18 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.434); catalogued as COSV99480820; called by muse, mutect2, varscan2
- CLIP4 | c.1175C>T p.T392I | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100191916; called by muse, mutect2, varscan2
- CLN5 | c.41G>T p.R14L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.097); catalogued as rs1452146675, COSV101080306; called by muse, mutect2, varscan2
- CMBL | c.324-1G>C p.X108_splice | Splice Site (SNP) | VAF 3/24 reads (13%) | catalogued as rs979254805, COSV99687023; called by muse, mutect2
- COL25A1 | c.1292A>T p.Y431F | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV101211425; called by muse, mutect2, varscan2
- COL6A6 | c.3009C>G p.F1003L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV100649693, COSV100650273; called by muse, mutect2, varscan2
- COLEC12 | c.1565C>A p.S522Y | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs1299752627, COSV101232072; called by muse, mutect2, varscan2
- CPE | c.649A>G p.K217E | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.158); catalogued as COSV101291586; called by muse, mutect2, varscan2
- CPO | c.75A>T p.L25F | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.221); catalogued as COSV99786501; called by muse, mutect2
- CR2 | c.1843G>T p.G615C | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100889640; called by muse, mutect2, varscan2
- CSMD3 | c.10438G>T p.A3480S (on ENST00000297405 / NM_001363185.1; = p.A3311S on NM_052900.3) | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.039); catalogued as COSV99834637; called by muse, mutect2, varscan2
- CWH43 | c.1358T>A p.L453Q | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV99893430; called by muse, mutect2, varscan2
- DAB2 | c.1691C>G p.S564* | Nonsense Mutation (SNP) | VAF 17/67 reads (25%) | catalogued as COSV100298024; called by muse, mutect2, varscan2
- DBR1 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.054); catalogued as rs1559881994, COSV53430195; called by muse, mutect2, varscan2
- DCC | c.512T>C p.I171T | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.162); catalogued as COSV100500140; called by muse, mutect2, varscan2
- DENND1C | c.221C>A p.T74K | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101200203; called by muse, mutect2, varscan2
- DGKI | c.2652G>A p.W884* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as COSV55981114; called by muse, mutect2, varscan2
- DHFR2 | c.489C>G p.Y163* | Nonsense Mutation (SNP) | VAF 37/147 reads (25%) | catalogued as COSV100113287; called by muse, mutect2, varscan2
- DHRS4 | c.307-2A>G p.X103_splice | Splice Site (SNP) | VAF 262/434 reads (60%) | catalogued as COSV100365888; called by muse, mutect2, varscan2
- DHX35 | c.1838G>T p.G613V | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99326858; called by muse, mutect2, varscan2
- DHX36 | c.410A>G p.E137G | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100273604; called by muse, mutect2, varscan2
- DISP2 | c.1523G>T p.R508L | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV51122883, COSV99139998; called by muse, mutect2, varscan2
- DISP2 | c.2531G>T p.W844L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs1374417590, COSV99140000, COSV99140657; called by muse, mutect2, varscan2
- DLC1 | c.1187G>C p.G396A | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.138); catalogued as COSV99363182; called by muse, mutect2, varscan2
- DNAH5 | c.11316G>T p.Q3772H | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99449876; called by muse, mutect2, varscan2
- DNAH8 | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.104); catalogued as COSV100545366, COSV59473950; called by muse, mutect2, varscan2
- DNAJC11 | c.949G>T p.D317Y | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV53791123, COSV99602181; called by muse, mutect2, varscan2
- DNASE2B | c.211A>G p.R71G | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1196330295, COSV101042903; called by muse, mutect2, varscan2
- DPYD | c.580G>T p.G194C | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100929080; called by muse, mutect2, varscan2
- DSG4 | c.1850C>G p.T617S | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV100355921; called by muse, mutect2, varscan2
- DST | c.12034A>T p.R4012* (on ENST00000361203 / NM_001374722.1; = p.R1600* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 8/144 reads (6%) | catalogued as COSV99756042; called by muse, mutect2
- DTX1 | c.1796G>C p.S599T | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs1566023551, COSV99921730; called by muse, mutect2, varscan2
- DYNC1I1 | c.1903A>G p.S635G | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100268383; called by muse, mutect2, varscan2
- EBF1 | c.1129G>A p.V377I | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs768070173, COSV100565782, COSV58192731; called by muse, mutect2, varscan2
- EBF2 | c.1664C>G p.A555G | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.103); catalogued as COSV101282173; called by muse, mutect2, varscan2
- ECHDC1 | c.382-2A>T p.X128_splice (on ENST00000531967 / NM_001139510.1; = p.X122_splice on NM_001002030.2) | Splice Site (SNP) | VAF 33/91 reads (36%) | catalogued as COSV100541747; called by muse, mutect2, varscan2
- EDC3 | c.378G>T p.Q126H | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.453); catalogued as COSV100165951; called by muse, mutect2, varscan2
- ENC1 | c.208T>C p.Y70H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100188055; called by muse, mutect2, varscan2
- ENTHD1 | c.562C>A p.L188I | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as COSV100288759; called by muse, mutect2, varscan2
- EPHB1 | c.1803G>T p.E601D | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV101213181; called by muse, mutect2, varscan2
- EPS15L1 | c.373-2A>G p.X125_splice | Splice Site (SNP) | VAF 43/105 reads (41%) | catalogued as COSV99933103; called by muse, mutect2, varscan2
- ERC2 | c.728A>T p.Q243L | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV99884849; called by muse, mutect2, varscan2
- EXOC6B | c.111C>G p.L37= | Splice Region (SNP) | VAF 15/56 reads (27%) | catalogued as COSV99724251; called by muse, mutect2, varscan2
- EYS | c.1442G>A p.W481* | Nonsense Mutation (SNP) | VAF 9/63 reads (14%) | catalogued as COSV100676460; called by muse, mutect2, varscan2
- F13B | c.1361G>T p.C454F | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100803288, COSV100803445; called by muse, mutect2, varscan2
- FADS2 | c.747C>T p.Y249= | Splice Region (SNP) | VAF 24/95 reads (25%) | catalogued as rs143661125; called by muse, mutect2, varscan2
- FAM172A | c.856A>C p.N286H | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.58); catalogued as COSV101232750; called by muse, mutect2
- FAM47B | c.1714C>A p.P572T | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as rs1310731534, COSV100264339; called by muse, mutect2, varscan2
- FAM47C | c.677C>A p.P226H | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV63729215, COSV63729946; called by muse, mutect2, varscan2
- FANCB | c.1437G>T p.W479C | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100146548; called by muse, mutect2, varscan2
- FAT1 | c.9854G>T p.G3285V | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1374317180, COSV101499349, COSV71673613; called by muse, mutect2
- FBXO24 | c.545G>A p.R182H (on ENST00000241071 / NM_033506.3; = p.R220H on NM_012172.5) | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.247); catalogued as rs747841487, COSV53829112; called by muse, mutect2, varscan2
- FGF23 | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs868121222, COSV99031707, COSV99031715; called by muse, mutect2, varscan2
- FNDC3B | c.3258C>A p.N1086K | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.027); catalogued as COSV100394175; called by muse, mutect2, varscan2
- FOLH1 | c.254G>T p.G85V | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99923218; called by muse, mutect2, varscan2
- FOLH1 | c.253G>T p.G85* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | catalogued as COSV99923219; called by muse, mutect2, varscan2
- GALNT13 | c.401C>T p.T134I | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101223009; called by muse, mutect2, varscan2
- GALNT5 | c.213A>G p.I71M | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs763774113, COSV99375189; called by muse, mutect2, varscan2
- GFM1 | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99962907; called by muse, mutect2, varscan2
- GIMAP4 | c.716C>A p.A239E | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.053); catalogued as COSV99750694; called by muse, mutect2, varscan2
- GJD4 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0.009); catalogued as rs1193854854, COSV100397223; called by muse, mutect2, varscan2
- GLI3 | c.2326G>C p.E776Q | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV101229874; called by muse, mutect2, varscan2
- GLS2 | c.311C>G p.S104* | Nonsense Mutation (SNP) | VAF 22/147 reads (15%) | catalogued as COSV100358357; called by muse, mutect2, varscan2
- GNG11 | c.101C>G p.S34C | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99949349; called by muse, mutect2, varscan2
- GPR141 | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0.027); catalogued as rs1358038827, COSV100550322; called by muse, mutect2, varscan2
- GPR158 | c.990C>A p.C330* | Nonsense Mutation (SNP) | VAF 18/61 reads (30%) | catalogued as COSV100893562; called by muse, mutect2, varscan2
- GPR78 | c.907C>A p.Q303K | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101223972; called by muse, mutect2, varscan2
- GREB1 | c.5419G>A p.A1807T | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.438); catalogued as rs765831845, COSV99302932; called by muse, mutect2, varscan2
- GRHL2 | c.178A>G p.S60G | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.606); catalogued as COSV99306949; called by muse, mutect2, varscan2
- GRIA1 | c.2021G>T p.R674M | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs1176067087, COSV99599866; called by muse, mutect2, varscan2
- GUCY1A1 | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.381); catalogued as COSV99637776; called by muse, mutect2, varscan2
- GUSB | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100512627; called by muse, mutect2, varscan2
- H2AC6 | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.306); catalogued as COSV100019903; called by muse, mutect2, varscan2
- HACD1 | c.305G>C p.G102A | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs1554816821, COSV100778494, COSV63516369; called by muse, mutect2, varscan2
- HGD | c.1317G>T p.R439S | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV52197276, COSV99380968; called by muse, mutect2, varscan2
- HGD | c.1316G>T p.R439M | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV99380969; called by muse, mutect2, varscan2
- HOXA6 | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs764072162, COSV56074356, COSV99762314; called by muse, mutect2, varscan2
- HOXD3 | c.371C>G p.P124R | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as rs140883088, COSV50885898; called by muse, mutect2, varscan2
- HTATSF1 | c.703G>T p.D235Y | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as COSV99511654; called by muse, mutect2, varscan2
- IFI27L1 | c.113C>A p.S38* | Nonsense Mutation (SNP) | VAF 9/51 reads (18%) | catalogued as COSV101267237; called by muse, mutect2, varscan2
- IGKV2-24 | c.148G>C p.V50L | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368646335; called by muse, mutect2, varscan2
- IGSF9 | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 13/43 reads (30%) | catalogued as COSV100829627; called by muse, mutect2, varscan2
- IL12RB2 | c.2324C>G p.S775C | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV99255080; called by muse, mutect2, varscan2
- IL18R1 | c.1213G>T p.E405* | Nonsense Mutation (SNP) | VAF 14/64 reads (22%) | catalogued as COSV99295122; called by muse, mutect2, varscan2
- INSL6 | c.253A>T p.T85S | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.023); catalogued as COSV101068477; called by muse, mutect2, varscan2
- INTS11 | c.1054G>T p.G352C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100028324; called by muse, mutect2, varscan2
- ITCH | c.971C>G p.T324S (on ENST00000262650 / NM_001257137.3; = p.T283S on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99392484; called by muse, mutect2, varscan2
- ITIH6 | c.832C>A p.P278T | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV99513320; called by muse, mutect2, varscan2
- KCNU1 | c.2644G>T p.G882W | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1164131796, COSV101299201; called by muse, mutect2, varscan2
- KDR | c.3143G>T p.G1048V | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55758023; called by muse, mutect2, varscan2
- KHK | c.167C>G p.P56R | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV99566126; called by muse, mutect2, varscan2
- KIAA1755 | c.2445G>T p.L815F | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99642043; called by muse, mutect2, varscan2
- KIF13B | c.1025C>G p.S342* | Nonsense Mutation (SNP) | VAF 32/112 reads (29%) | catalogued as COSV73054142; called by muse, mutect2, varscan2
- KLHL1 | c.409G>T p.G137* | Nonsense Mutation (SNP) | VAF 30/82 reads (37%) | catalogued as COSV100917290; called by muse, mutect2, varscan2
- KRT17 | c.490C>A p.L164M | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100245139; called by muse, mutect2, varscan2
- LARS1 | c.841G>T p.G281C (on ENST00000394434 / NM_020117.11; = p.G254C on NM_016460.3) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.109); catalogued as rs1482145633, COSV99198606; called by muse, mutect2, varscan2
- LATS2 | c.2195A>G p.Y732C | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101231571; called by muse, mutect2, varscan2
- LCOR | c.3477G>C p.R1159S | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV99616889; called by muse, mutect2, varscan2
- LCTL | c.71A>T p.K24M | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.101); catalogued as COSV100427213; called by muse, mutect2
- LILRB4 | c.74C>A p.P25H | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs755568653, COSV54407497; called by muse, mutect2, varscan2
- LRP1B | c.8185G>C p.A2729P | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV101256084, COSV101257161, COSV67201434; called by muse, mutect2, varscan2
- LRP1B | c.5294G>C p.G1765A | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV101257163; called by muse, mutect2
- LRP2 | c.7945C>A p.Q2649K | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV99788523; called by muse, mutect2, varscan2
- LRRC27 | c.1304G>C p.R435T | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as COSV100889847; called by muse, mutect2, varscan2
- LRRC66 | c.2308G>T p.E770* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as COSV100602964; called by muse, mutect2, varscan2
- LRRIQ1 | c.4124A>G p.K1375R | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV101280341; called by muse, mutect2, varscan2
- LRRIQ4 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs267599688, COSV100540244; called by muse, mutect2, varscan2
- LRRK2 | c.6013C>A p.L2005M | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100110205; called by muse, mutect2, varscan2
- LRRN2 | c.1720C>T p.R574C | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs778876933, COSV100912789, COSV99057093; called by muse, mutect2, varscan2
- LTBP4 | c.779G>T p.R260L (on ENST00000308370 / NM_001042544.1; = p.R223L on NM_003573.2) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as rs764926563, COSV99180389, COSV99192617; called by muse, mutect2, varscan2
- LYNX1-SLURP2 | c.244G>T p.V82F | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as rs1217625717, COSV100235595; called by muse, mutect2, varscan2
- MAN1B1 | c.280C>G p.L94V | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1332543457, COSV100814447; called by muse, mutect2, varscan2
- MAP3K10 | c.2693C>T p.P898L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.371); catalogued as rs1568496618, COSV99454376; called by muse, mutect2, varscan2
- MAP3K15 | c.1150G>T p.D384Y | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100134756; called by muse, mutect2, varscan2
- MARK2 | c.712G>A p.V238I | Missense Mutation (SNP) | VAF 73/294 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV100158605; called by muse, mutect2, varscan2
- MAS1L | c.759C>G p.C253W | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs370874813, COSV101009686; called by muse, mutect2
- MED12 | c.3916G>A p.D1306N | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.222); catalogued as COSV100378402, COSV61338831; called by muse, mutect2, varscan2
- MIB1 | c.1283C>G p.S428C | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs1469916484, COSV99838803; called by muse, mutect2, varscan2
- MICB | c.823G>C p.G275R | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV99357431; called by muse, mutect2, varscan2
- MICB | c.824G>T p.G275V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52855486, COSV99357432; called by muse, mutect2, varscan2
- MID1IP1 | c.470T>C p.V157A | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100423716; called by muse, mutect2
- MLXIP | c.1477A>T p.T493S | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs781014276, COSV100038772; called by muse, mutect2, varscan2
- MTERF3 | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.001); catalogued as COSV99749772; called by muse, mutect2, varscan2
- MTF1 | c.919A>G p.K307E | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV100888636; called by muse, mutect2, varscan2
- MTSS2 | c.458-1G>C p.X153_splice | Splice Site (SNP) | VAF 8/44 reads (18%) | catalogued as COSV58697865; called by muse, mutect2, varscan2
- MUC16 | c.41894A>T p.Q13965L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.846); catalogued as rs753045053, COSV101109905; called by muse, varscan2
- MUC16 | c.6263C>A p.T2088N | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV101199974; called by muse, mutect2, varscan2
- MUC17 | c.3184C>G p.L1062V | Missense Mutation (SNP) | VAF 84/362 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as COSV100073309; called by muse, mutect2, varscan2
- MUC17 | c.5231C>G p.P1744R | Missense Mutation (SNP) | VAF 88/348 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as rs576323320, COSV100073310; called by muse, mutect2, varscan2
- MYH13 | c.1460T>A p.L487Q | Missense Mutation (SNP) | VAF 94/181 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99354012; called by muse, mutect2, varscan2
- MYH15 | c.5555C>T p.A1852V | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs1189524287, COSV99843303; called by muse, mutect2, varscan2
- NCAPD2 | c.3940C>G p.P1314A | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV99975519; called by muse, mutect2, varscan2
- NCMAP | c.58A>G p.R20G | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100980292; called by muse, mutect2, varscan2
- NCOA1 | c.3872G>C p.G1291A | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.234); catalogued as COSV99946068; called by muse, mutect2
- NECTIN4 | c.29G>C p.W10S | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV100919916; called by muse, mutect2, varscan2
- NEFH | c.2859G>C p.E953D | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.066); catalogued as COSV100151567; called by muse, mutect2, varscan2
- NID2 | c.3244C>A p.P1082T | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1385852761, COSV99356554; called by muse, mutect2, varscan2
- NLRP8 | c.229G>T p.E77* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as COSV52586652, COSV99405303; called by muse, mutect2, varscan2
- NOVA1 | c.847G>T p.A283S | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.971); catalogued as COSV57490552; called by muse, mutect2, varscan2
- NRAP | c.179A>G p.K60R | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.204); catalogued as COSV100748440; called by muse, mutect2
- NUDT6 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV99144650; called by muse, mutect2, varscan2
- NUMB | c.890G>A p.R297H (on ENST00000355058; = p.R286H on NM_003744.5) | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1259984994, COSV100679690; called by muse, mutect2, varscan2
- NXPH3 | c.64G>A p.G22S | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.346); catalogued as rs1194162142, COSV100165525; called by muse, mutect2, varscan2
- OBSCN | c.14912G>C p.C4971S | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99478205; called by muse, mutect2, varscan2
- OCRL | c.1667G>A p.R556K | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV100843446; called by muse, mutect2, varscan2
- OGDH | c.2377G>A p.A793T | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs762244199, COSV56045544; called by muse, mutect2, varscan2
- OR11L1 | c.924A>T p.K308N | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100869430; called by muse, mutect2
- OR4F17 | c.4G>A p.V2M | Missense Mutation (SNP) | VAF 44/482 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as COSV100535555; called by muse, mutect2
- OR5K3 | c.687G>T p.K229N | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV101051647; called by muse, mutect2, varscan2
- OR8K3 | c.360C>G p.Y120* | Nonsense Mutation (SNP) | VAF 21/66 reads (32%) | catalogued as COSV100449783, COSV57131669; called by muse, mutect2, varscan2
- OR9G1 | c.12C>A p.S4R | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100380412; called by muse, mutect2, varscan2
- OTOGL | c.2861G>T p.R954L (on ENST00000547103; = p.R945L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV101509269, COSV72007311; called by muse, mutect2, varscan2
- OXR1 | c.307-1G>T p.X103_splice (on ENST00000442977 / NM_001198532.1; = p.X102_splice on NM_018002.3) | Splice Site (SNP) | VAF 13/63 reads (21%) | catalogued as rs1416096612, COSV100367276; called by muse, mutect2, varscan2
- P4HA1 | c.811A>G p.T271A | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV99696907; called by muse, mutect2, varscan2
- PAK5 | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100781346; called by muse, mutect2, varscan2
- PARVA | c.751G>C p.D251H | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100616614; called by muse, mutect2, varscan2
- PCDHA3 | c.1794T>A p.D598E | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100793449; called by muse, mutect2, varscan2
- PCDHGB5 | c.1006G>T p.E336* | Nonsense Mutation (SNP) | VAF 23/76 reads (30%) | catalogued as rs1054849184; called by muse, mutect2, varscan2
- PCLO | c.2902C>G p.P968A | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as COSV100432059, COSV100432821; called by muse, mutect2, varscan2
- PDE3A | c.1173C>A p.H391Q | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); catalogued as COSV100762114; called by muse, mutect2, varscan2
- PHF8 | c.445G>A p.V149M (on ENST00000357988 / NM_001184896.1; = p.V113M on NM_015107.3) | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.456); catalogued as rs1557108684, COSV100154207; called by muse, mutect2
- PKD2L1 | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as COSV100559379; called by muse, mutect2, varscan2
- PLCB2 | c.3406del p.A1136Qfs*3 | Frame Shift Del (DEL) | VAF 25/77 reads (32%) | catalogued as COSV53031249; called by mutect2, pindel, varscan2
- PLCH1 | c.1807G>C p.D603H (on ENST00000340059 / NM_001130960.2; = p.D615H on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100396910, COSV100397012, COSV58208727; called by muse, mutect2, varscan2
- PLXNB3 | c.3017C>T p.A1006V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV100737457, COSV62800000; called by muse, mutect2, varscan2
- PNLIPRP3 | c.430G>T p.V144L | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.105); catalogued as COSV100982485; called by muse, mutect2, varscan2
- POU2F1 | c.213G>C p.Q71H (on ENST00000541643 / NM_001365848.1; = p.Q94H on NM_002697.4) | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.948); catalogued as COSV99611146; called by muse, mutect2, varscan2
- PPFIA2 | c.2630G>C p.R877T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as rs760964134, COSV100331366, COSV100333437; called by muse, mutect2, varscan2
- PPFIA2 | c.1036C>A p.R346S | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100333438, COSV61030798; called by muse, mutect2, varscan2
- PPP1R3A | c.1795G>C p.E599Q | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.086); catalogued as COSV99492915, COSV99492960; called by muse, mutect2, varscan2
- PRAMEF12 | c.341G>A p.G114D | Missense Mutation (SNP) | VAF 52/194 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV100743283; called by muse, mutect2, varscan2
- PRDM10 | c.541G>C p.A181P | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV100456793; called by muse, mutect2, varscan2
- PRKN | c.29G>T p.S10I | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100629148; called by muse, mutect2, varscan2
- PRODH2 | c.475C>A p.Q159K (on ENST00000301175; = p.Q83K on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99995321; called by muse, mutect2, varscan2
- PROX1 | c.723G>T p.Q241H | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.69); catalogued as COSV99799440; called by muse, mutect2, varscan2
- PRSS38 | c.29C>G p.P10R | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.007); catalogued as COSV100816485; called by muse, mutect2, varscan2
- PTPRK | c.3256G>T p.A1086S (on ENST00000368215 / NM_001291984.2; = p.A1087S on NM_002844.4) | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.854); catalogued as COSV100951101; called by muse, mutect2, varscan2
- PWP1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 22/76 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.775); catalogued as COSV101338818; called by muse, mutect2, varscan2
- PZP | c.2488G>C p.V830L | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99737883; called by muse, mutect2, varscan2
- RAB11FIP1 | c.3737T>A p.F1246Y (on ENST00000330843 / NM_001002814.3; = p.F612Y on NM_025151.5) | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.953); catalogued as COSV99770070; called by muse, mutect2, varscan2
- RAB5B | c.424A>G p.M142V | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1191940197, COSV64365162; called by muse, mutect2, varscan2
- RADIL | c.937G>T p.G313W | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as rs1483618238, COSV101271419, COSV68203492; called by muse, mutect2, varscan2
- RASA2 | c.952G>C p.D318H | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99656163; called by muse, mutect2, varscan2
- RASSF9 | c.179A>G p.H60R | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as rs767448968, COSV100771377; called by muse, mutect2, varscan2
- RBM38 | c.381G>T p.Q127H | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as COSV100654830; called by muse, mutect2, varscan2
- REV3L | c.1321G>C p.G441R | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV100725197; called by muse, mutect2, varscan2
- RHOBTB1 | c.1845G>A p.W615* | Nonsense Mutation (SNP) | VAF 32/100 reads (32%) | catalogued as rs1319214200, COSV100558477, COSV61959863; called by muse, mutect2, varscan2
- RNF148 | c.632G>T p.W211L | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.005); catalogued as COSV57394032; called by muse, mutect2, varscan2
- ROBO2 | c.3406G>T p.G1136C | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV100166843; called by muse, mutect2, varscan2
- RP1 | c.4737A>T p.L1579F | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99607526; called by muse, mutect2, varscan2
- RSF1 | c.1694A>T p.K565I | Missense Mutation (SNP) | VAF 22/257 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.209); catalogued as COSV100407227; called by muse, mutect2
- RTN4 | c.3133T>G p.L1045V (on ENST00000337526 / NM_020532.5; = p.L52V on NM_007008.3) | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100463207; called by muse, mutect2, varscan2
- RXFP3 | c.1217G>C p.R406P | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV100347548, COSV100347603; called by muse, mutect2, varscan2
- RYR1 | c.2506C>A p.P836T | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.474); catalogued as COSV100615748; called by muse, mutect2, varscan2
- RYR2 | c.184C>A p.L62I | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.503); catalogued as CM097947, COSV100770285; called by muse, mutect2, varscan2
- RYR2 | c.6614G>A p.R2205H | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370276573; called by muse, mutect2, varscan2
- SCAP | c.3415G>C p.D1139H | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99650583; called by muse, mutect2, varscan2
- SCN1A | c.2548G>T p.A850S (on ENST00000303395 / NM_001202435.3; = p.A839S on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV100320463, COSV57682879; called by muse, mutect2, varscan2
- SCN4A | c.171C>A p.D57E | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as rs1415923721, COSV101438487; called by muse, mutect2, varscan2
- SH3PXD2A | c.1615A>G p.T539A (on ENST00000369774 / NM_001365079.1; = p.T511A on NM_014631.2) | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs975966157, COSV100280118; called by muse, mutect2, varscan2
- SLA | c.286G>A p.E96K (on ENST00000338087 / NM_001045556.3; = p.E136K on NM_006748.4) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV99600919; called by muse, mutect2, varscan2
- SLC16A7 | c.1093C>T p.L365F | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99676516; called by muse, mutect2, varscan2
- SLC17A8 | c.130G>C p.D44H | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as COSV100035536; called by muse, mutect2, varscan2
- SLC26A7 | c.399C>A p.S133R | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.301); catalogued as rs561154188, COSV52591413, COSV99403388; called by muse, mutect2, varscan2
- SLC30A6 | c.546C>G p.S182R | Missense Mutation (SNP) | VAF 49/200 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as rs762269321, COSV99249662; called by muse, mutect2, varscan2
- SLC35G5 | c.598G>T p.G200C | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99644272; called by muse, mutect2, varscan2
- SLC39A4 | c.1907T>A p.L636Q (on ENST00000301305 / NM_001374839.1; = p.L611Q on NM_017767.3) | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99433359; called by muse, mutect2, varscan2
- SLC9A1 | c.1737G>C p.K579N | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV99849705; called by muse, mutect2, varscan2
- SLCO6A1 | c.1399A>T p.I467L | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.078); catalogued as COSV101134346, COSV65806334; called by muse, mutect2
- SLTM | c.2323G>C p.E775Q | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs776972438, COSV100998670, COSV65848258; called by muse, mutect2, varscan2
- SMPDL3A | c.1255A>T p.T419S | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.66); PolyPhen benign (0.01); catalogued as COSV100868694; called by muse, mutect2, varscan2
- SNW1 | c.119A>T p.E40V | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.018); catalogued as rs1311977656, COSV99834353; called by muse, mutect2, varscan2
- SP4 | c.1679-1G>T p.X560_splice | Splice Site (SNP) | VAF 12/42 reads (29%) | catalogued as rs1439997031, COSV99754468; called by muse, mutect2, varscan2
- SPANXN2 | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 86/249 reads (35%) | catalogued as COSV100979895, COSV65128776; called by muse, mutect2, varscan2
- SPATA13 | c.1490A>C p.Y497S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.133); catalogued as COSV100542247; called by muse, mutect2, varscan2
- SPG11 | c.1380G>T p.M460I | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99968689; called by muse, mutect2
- SPOCK3 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.212); catalogued as rs748124901, COSV100693020, COSV62727491; called by muse, mutect2, varscan2
- STEAP3 | c.393G>C p.E131D | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV100713312; called by muse, mutect2, varscan2
- STXBP5L | c.3271G>A p.G1091R | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); catalogued as rs756746175, COSV99874188; called by muse, mutect2, varscan2
- SV2A | c.1613A>G p.D538G | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100975163; called by muse, mutect2, varscan2
- SV2C | c.1698G>T p.K566N | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as rs1165035597, COSV100456166; called by muse, mutect2, varscan2
- SYTL2 | c.140A>G p.K47R | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.919); catalogued as COSV100314265; called by muse, mutect2, varscan2
- TAF1L | c.2112G>T p.E704D | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99644727; called by muse, mutect2, varscan2
- TAF5L | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.484); catalogued as COSV51088565, COSV99273057, COSV99273174; called by muse, mutect2, varscan2
- TBCK | c.733A>G p.T245A (on ENST00000273980 / NM_001163436.4; = p.T182A on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs145662552; called by muse, mutect2, varscan2
- TBX18 | c.1462C>G p.Q488E | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); catalogued as COSV100858514; called by muse, mutect2, varscan2
- TECRL | c.209G>T p.R70M | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as COSV67086476; called by muse, mutect2, varscan2
- TGM2 | c.1319C>G p.T440S | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100821626; called by muse, mutect2, varscan2
- TMCC3 | c.439G>T p.G147* | Nonsense Mutation (SNP) | VAF 38/126 reads (30%) | catalogued as COSV99705463; called by muse, mutect2, varscan2
- TMEM132B | c.1255G>T p.V419L | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.105); catalogued as COSV100169719, COSV100170691; called by muse, mutect2, varscan2
- TMEM132E | c.1212G>T p.K404N (on ENST00000321639; = p.K494N on NM_001304438.2) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778543780, COSV100396321; called by muse, mutect2, varscan2
- TMEM39A | c.459G>T p.M153I | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs1183570566, COSV100052410; called by muse, mutect2, varscan2
- TMEM61 | c.218G>T p.C73F | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV100987745; called by muse, mutect2, varscan2
- TMIGD2 | c.149C>A p.T50K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100010289; called by muse, mutect2, varscan2
- TNFRSF11A | c.1633G>C p.D545H | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99500231; called by muse, mutect2, varscan2
- TPO | c.1687A>G p.R563G | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV100221058; called by muse, mutect2, varscan2
- TPO | c.2570T>C p.L857P | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV100221061; called by muse, mutect2, varscan2
- TRIM62 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as rs1275310412, COSV99357807; called by muse, mutect2, varscan2
- TRPC3 | c.1977G>T p.M659I (on ENST00000379645 / NM_001366479.2; = p.M586I on NM_003305.2) | Missense Mutation (SNP) | VAF 58/260 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV99312670; called by mutect2, varscan2
- TRPC3 | c.1382C>A p.A461E (on ENST00000379645 / NM_001366479.2; = p.A388E on NM_003305.2) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.917); catalogued as COSV53378029; called by muse, mutect2, varscan2
- TRRAP | c.10006-1G>T p.X3336_splice (on ENST00000359863 / NM_001244580.1; = p.X3307_splice on NM_003496.3) | Splice Site (SNP) | VAF 36/150 reads (24%) | catalogued as COSV100722490; called by muse, mutect2, varscan2
- TTN | c.46111C>T p.L15371F (on ENST00000591111; = p.L7947F on NM_003319.4) | Missense Mutation (SNP) | VAF 18/74 reads (24%) | PolyPhen probably damaging (0.999); catalogued as COSV100613053; called by muse, mutect2, varscan2
- TTPA | c.366G>T p.W122C | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52646790, COSV52648687, COSV99478520; called by muse, mutect2, varscan2
- TUBA4A | c.513C>G p.I171M | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV99944788; called by muse, mutect2, varscan2
- UNC79 | c.2723C>G p.P908R (on ENST00000393151 / NM_001346218.2; = p.P731R on NM_020818.5) | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.189); catalogued as COSV99827912; called by muse, mutect2, varscan2
- VWA5A | c.2177C>T p.A726V | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1295455862, COSV100827870; called by muse, mutect2, varscan2
- WDFY3 | c.1357T>A p.F453I | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV99883586; called by muse, mutect2, varscan2
- WDFY3 | c.254C>T p.S85L | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV55704884, COSV99883587; called by muse, mutect2, varscan2
- WDR17 | c.2029G>T p.V677L | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.996); catalogued as COSV54580777; called by muse, mutect2, varscan2
- WDR33 | c.3266G>T p.R1089L | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.1); catalogued as rs754393530, COSV59247538, COSV59248900; called by muse, mutect2, varscan2
- XIRP1 | c.4307C>G p.T1436S | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as rs777447329, COSV100453657; called by muse, mutect2, varscan2
- XKR4 | c.305G>T p.R102M | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.962); catalogued as COSV100532590, COSV59308237; called by muse, mutect2, varscan2
- XRN1 | c.587C>G p.P196R | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV99378003; called by muse, mutect2, varscan2
- ZFHX3 | c.8156T>C p.L2719P | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99212337; called by muse, mutect2, varscan2
- ZFPM2 | c.3151G>T p.D1051Y | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.185); catalogued as rs1355875943, COSV101023228; called by muse, mutect2, varscan2
- ZIC1 | c.835G>T p.E279* | Nonsense Mutation (SNP) | VAF 24/125 reads (19%) | catalogued as COSV51556104, COSV99291933; called by muse, mutect2, varscan2
- ZIC4 | c.97C>A p.Q33K | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0.01); catalogued as rs1265877578, COSV101267973; called by muse, mutect2, varscan2
- ZNF226 | c.2131G>T p.A711S | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as COSV100335145; called by muse, mutect2, varscan2
- ZNF25 | c.278A>T p.Q93L | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV100224620; called by muse, mutect2, varscan2
- ZNF276 | c.1456G>T p.V486L (on ENST00000443381 / NM_001113525.2; = p.V411L on NM_152287.4) | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs144982544, COSV99234949; called by mutect2, varscan2
- ZNF280A | c.1031C>A p.P344H | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV100131058; called by muse, mutect2, varscan2
- ZNF479 | c.1470G>T p.E490D | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.949); catalogued as COSV100482754, COSV58637090; called by muse, mutect2, varscan2
- ZNF521 | c.1620T>G p.S540R | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.285); catalogued as COSV100832218, COSV64126939; called by muse, mutect2, varscan2
- ZNF536 | c.476A>G p.K159R | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV62833523; called by muse, mutect2, varscan2
- ZNF804A | c.2768C>A p.A923D | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV100167951, COSV56456527; called by muse, mutect2, varscan2
- ZPBP | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs559157574, COSV50431923; called by muse, mutect2, varscan2
- ZSWIM4 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.405); catalogued as rs1379334150, COSV99584906; called by muse, mutect2, varscan2
- ADAM22 | c.2418del p.L807Sfs*88 (on ENST00000265727 / NM_001324420.2; = p.L807Sfs*78 on NM_004194.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | called by mutect2, pindel, varscan2
- ASAH2 | c.682T>A p.L228M | Missense Mutation (SNP) | VAF 46/199 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CADPS2 | c.991del p.E331Nfs*7 | Frame Shift Del (DEL) | VAF 19/85 reads (22%) | called by mutect2, pindel, varscan2
- CATSPER2 | c.299_300insT p.W100Cfs*7 | Frame Shift Ins (INS) | VAF 5/31 reads (16%) | called by mutect2, pindel*, varscan2
- DYRK4 | c.367del p.D123Ifs*10 | Frame Shift Del (DEL) | VAF 31/122 reads (25%) | called by mutect2, pindel, varscan2
- FAM47B | c.1514_1517del p.A505Efs*3 | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | called by mutect2, pindel, varscan2
- GNRHR | c.476_480del p.M159Rfs*8 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | called by mutect2, pindel
- IGKV1-9 | c.301C>A p.Q101K | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.038); called by muse, mutect2
- MMP28 | c.577G>T p.G193W | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR10AG1 | c.36dup p.N13Qfs*8 | Frame Shift Ins (INS) | VAF 26/99 reads (26%) | called by mutect2, pindel, varscan2
- PPIAL4A | c.261C>A p.N87K | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SI | c.3998dup p.V1334Gfs*12 | Frame Shift Ins (INS) | VAF 8/64 reads (13%) | called by mutect2, pindel, varscan2
- SUPT20HL2 | c.720G>T p.Q240H | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- TMEM236 | c.14G>T p.R5M | Missense Mutation (SNP) | VAF 103/437 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- TRGV4 | c.115A>T p.I39F | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- UTP25 | c.388+2_388+8delinsG p.X130_splice | Splice Site (DEL) | VAF 14/63 reads (22%) | called by pindel, varscan2*
- VN1R5 | c.748C>A p.L250I | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- ABCA9 | c.4800G>A p.E1600= | Silent (SNP) | VAF 38/61 reads (62%) | catalogued as rs1441575789, COSV100382806; called by muse, mutect2, varscan2
- ABCC3 | c.3852C>T p.P1284= | Silent (SNP) | VAF 38/68 reads (56%) | catalogued as rs1404534295, COSV99559169; called by muse, mutect2, varscan2
- ADAMTS15 | c.1911C>T p.D637= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs751495984, COSV100143393; called by muse, mutect2, varscan2
- ADRA1D | c.1038G>A p.A346= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs867469613, COSV101063008; called by muse, mutect2
- AMBRA1 | c.1929G>A p.E643= (on ENST00000458649 / NM_001367468.1; = p.E553= on NM_017749.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV100093982; called by muse, varscan2
- AMBRA1 | c.1863G>A p.R621= (on ENST00000458649 / NM_001367468.1; = p.R531= on NM_017749.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs1239704902, COSV100093984; called by muse, varscan2
- ANKRD26 | c.675G>A p.R225= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV63091891; called by muse, mutect2
- ARID4B | c.324G>A p.L108= | Silent (SNP) | VAF 37/128 reads (29%) | catalogued as COSV99935636; called by muse, mutect2, varscan2
- ASAH2 | c.681C>A p.I227= | Silent (SNP) | VAF 48/202 reads (24%) | called by muse, mutect2, varscan2
- BCL11B | c.87C>T p.I29= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as rs760433144, COSV61735982, COSV61738074; called by muse, mutect2, varscan2
- BCL9L | c.1743G>T p.R581= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs1044316605, COSV99419294; called by muse, mutect2
- C5orf38 | c.300C>T p.L100= | Silent (SNP) | VAF 35/119 reads (29%) | catalogued as COSV100121726; called by muse, mutect2, varscan2
- CACNA1E | c.6615T>A p.A2205= (on ENST00000367573 / NM_001205293.3; = p.A2162= on NM_000721.4) | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV100702677, COSV62408099; called by muse, mutect2, varscan2
- CCDC137 | c.588G>A p.V196= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as COSV100235710; called by muse, mutect2, varscan2
- CCNE2 | c.753C>A p.L251= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as rs1161622439, COSV100353761; called by muse, mutect2, varscan2
- CD300E | c.261C>T p.F87= | Silent (SNP) | VAF 54/84 reads (64%) | catalogued as COSV100151301; called by muse, mutect2, varscan2
- CDH18 | c.984C>A p.I328= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as rs909585998, COSV99934943; called by muse, mutect2, varscan2
- CLCN1 | c.2466C>T p.D822= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100578067; called by muse, mutect2, varscan2
- CNIH3 | c.375C>T p.A125= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as rs957414210, COSV99685544; called by muse, mutect2, varscan2
- DDX19B | c.1065A>G p.K355= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs1318037662, COSV99849974; called by muse, mutect2, varscan2
- DNAH3 | c.3897C>A p.S1299= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV99767514; called by muse, mutect2, varscan2
- DNMT3B | c.423G>A p.P141= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs755100690, COSV99140424; called by muse, mutect2, varscan2
- DPP6 | c.1095C>A p.T365= (on ENST00000377770 / NM_001364500.2; = p.T303= on NM_001936.5) | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV100125657; called by muse, mutect2, varscan2
- DYNC1H1 | c.7692C>G p.A2564= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV100794903; called by muse, mutect2
- EDEM3 | c.378A>T p.A126= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV100545302; called by muse, mutect2
- ETNPPL | c.708A>G p.V236= | Silent (SNP) | VAF 23/87 reads (26%) | catalogued as COSV99625254; called by muse, mutect2, varscan2
- FBXO2 | c.858G>T p.R286= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV100845331; called by muse, mutect2, varscan2
- FLNC | c.4254C>T p.D1418= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs773306584, COSV100367467; called by muse, mutect2, varscan2
- FYCO1 | c.444G>T p.S148= | Silent (SNP) | VAF 23/103 reads (22%) | catalogued as COSV99945672; called by muse, mutect2, varscan2
- GABRG2 | c.1515C>T p.L505= (on ENST00000361925 / NM_001375343.1; = p.L465= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 52/138 reads (38%) | catalogued as COSV100729696; called by muse, mutect2, varscan2
- GALM | c.177C>T p.F59= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs576534624, COSV99697225; called by muse, mutect2, varscan2
- GDF6 | c.1347G>T p.V449= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99748071; called by muse, mutect2
- GKN2 | c.291C>T p.L97= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as COSV100187816; called by muse, mutect2, varscan2
- GRIN2B | c.375C>A p.G125= | Silent (SNP) | VAF 32/129 reads (25%) | catalogued as COSV101663037; called by muse, mutect2, varscan2
- GUCY1A1 | c.198G>T p.R66= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as COSV99637774; called by muse, mutect2, varscan2
- GUCY1A2 | c.1770T>A p.A590= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV99974724; called by muse, mutect2
- HCN3 | c.981C>G p.L327= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV100855672; called by muse, mutect2, varscan2
- HELB | c.2706G>A p.G902= | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as rs532796415, COSV99921921; called by muse, mutect2, varscan2
- HES6 | c.492G>T p.G164= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV56029401, COSV99800751; called by muse, mutect2
- HHIPL2 | c.381G>C p.R127= | Silent (SNP) | VAF 39/165 reads (24%) | catalogued as COSV100596856; called by muse, mutect2, varscan2
- HMGCLL1 | c.1041T>C p.A347= | Silent (SNP) | VAF 12/141 reads (9%) | catalogued as COSV99232212; called by muse, mutect2
- IGHV1-69 | c.270C>A p.T90= | Silent (SNP) | VAF 122/331 reads (37%) | called by muse, mutect2, varscan2
- LRP5 | c.1923C>A p.I641= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV99592005; called by muse, mutect2, varscan2
- LRRC29 | c.399G>A p.L133= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV100440846; called by muse, mutect2, varscan2
- LSAMP | c.774A>T p.I258= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV100370615; called by muse, mutect2, varscan2
- MFSD5 | c.1059T>C p.A353= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV100289034; called by muse, mutect2, varscan2
- MMP16 | c.798A>G p.P266= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as rs1246921009, COSV99688283; called by muse, mutect2, varscan2
- MMP28 | c.579G>A p.G193= | Silent (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2
- MMRN1 | c.1317C>A p.A439= | Silent (SNP) | VAF 42/150 reads (28%) | catalogued as COSV99307124; called by muse, mutect2, varscan2
- MUC17 | c.8703C>A p.T2901= | Silent (SNP) | VAF 56/295 reads (19%) | catalogued as COSV100073312, COSV60287911; called by muse, mutect2, varscan2
- MYOM3 | c.1920G>A p.V640= | Silent (SNP) | VAF 41/108 reads (38%) | catalogued as COSV100292968; called by muse, mutect2, varscan2
- MYOT | c.1005T>A p.T335= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV99524931; called by muse, mutect2, varscan2
- MYPN | c.855A>G p.R285= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV100589982, COSV62733094; called by muse, mutect2, varscan2
- NALCN | c.927C>G p.L309= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV51957847, COSV99215251; called by muse, mutect2, varscan2
- NPHS1 | c.2715C>A p.T905= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs1487105643, COSV100799877, COSV62287980; called by muse, mutect2, varscan2
- NPNT | c.810A>G p.P270= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as COSV99975112; called by muse, mutect2
- OBSCN | c.19992C>T p.A6664= | Silent (SNP) | VAF 14/143 reads (10%) | catalogued as rs373513763; called by muse, mutect2
- OR2G2 | c.579G>T p.V193= | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as COSV60740074; called by muse, mutect2, varscan2
- OR5K3 | c.99C>A p.A33= | Silent (SNP) | VAF 46/215 reads (21%) | catalogued as COSV101051646; called by muse, mutect2, varscan2
- PCDH10 | c.3075G>C p.T1025= | Silent (SNP) | VAF 32/126 reads (25%) | catalogued as COSV99993586, COSV99994447; called by muse, mutect2, varscan2
- PCDHA8 | c.1785C>A p.R595= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as rs1265467066, COSV100969520, COSV65328510; called by muse, mutect2, varscan2
- PCDHGA12 | c.2025C>T p.L675= | Silent (SNP) | VAF 28/99 reads (28%) | catalogued as rs1208018612, COSV99340181; called by muse, mutect2, varscan2
- PKHD1L1 | c.6885T>A p.V2295= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV101006147; called by muse, mutect2
- POLR1G | c.390G>A p.L130= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as rs1378154645, COSV100338125; called by muse, mutect2, varscan2
- POU4F2 | c.1035G>A p.K345= | Silent (SNP) | VAF 31/114 reads (27%) | catalogued as COSV55586728; called by muse, mutect2, varscan2
- PRDM5 | c.1768C>A p.R590= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as rs387907110, CM114101, COSV53361001, COSV99310613; called by muse, mutect2, varscan2
- RALBP1 | c.1329G>A p.L443= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs1434636076, COSV99191936; called by muse, mutect2, varscan2
- RASIP1 | c.2874C>T p.P958= | Silent (SNP) | VAF 55/204 reads (27%) | catalogued as COSV55804377, COSV99710777; called by muse, mutect2, varscan2
- RHPN2 | c.1356C>G p.L452= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV54274262, COSV99577611; called by muse, mutect2, varscan2
- RO60 | c.813T>G p.A271= | Silent (SNP) | VAF 50/250 reads (20%) | catalogued as COSV100814381; called by muse, mutect2, varscan2
- ROM1 | c.396G>A p.A132= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs370599721; called by muse, mutect2, varscan2
- ROS1 | c.6762T>C p.N2254= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV100877083; called by muse, mutect2, varscan2
- RS1 | c.21C>A p.G7= | Silent (SNP) | VAF 32/158 reads (20%) | catalogued as COSV101183812; called by muse, mutect2, varscan2
- RUBCN | c.2769C>T p.C923= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as rs1560395216, COSV99584071; called by muse, mutect2
- RYR2 | c.6615T>A p.R2205= | Silent (SNP) | VAF 29/127 reads (23%) | catalogued as COSV100770286; called by muse, mutect2, varscan2
- SEC14L2 | c.1137C>T p.F379= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV99840829; called by muse, mutect2, varscan2
- SF1 | c.948C>T p.L316= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs750531001, COSV99918318; called by muse, mutect2, varscan2
- SIPA1L1 | c.2949C>T p.A983= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as COSV100665559; called by muse, mutect2, varscan2
- SLC22A18 | c.855C>T p.L285= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV100388809; called by muse, mutect2, varscan2
- SLC22A9 | c.621G>T p.G207= | Silent (SNP) | VAF 36/151 reads (24%) | catalogued as COSV99655020; called by muse, mutect2, varscan2
- STK4 | c.900G>C p.V300= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as COSV100860150; called by muse, mutect2, varscan2
- SUPT3H | c.930A>T p.P310= (on ENST00000371460 / NM_181356.3; = p.P299= on NM_003599.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV100177187; called by muse, mutect2, varscan2
- SWSAP1 | c.135T>C p.L45= (on ENST00000312423; = p.L66= on NM_175871.4) | Silent (SNP) | VAF 45/111 reads (41%) | catalogued as COSV99710142; called by muse, mutect2, varscan2
- TCEA2 | c.270G>T p.R90= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs1342453227, COSV100200355; called by muse, mutect2
- TMEM176B | c.96T>G p.A32= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as COSV99133737; called by muse, mutect2, varscan2
- UNC45B | c.139C>A p.R47= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs373866801, COSV99268707; called by muse, mutect2, varscan2
- UNC93A | c.237G>A p.V79= | Silent (SNP) | VAF 33/134 reads (25%) | catalogued as COSV100023309; called by muse, mutect2, varscan2
- USP35 | c.2445G>T p.L815= | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as COSV100416519; called by muse, mutect2, varscan2
- ZFHX4 | c.10305A>T p.P3435= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV99262837; called by muse, mutect2, varscan2
- ZMIZ2 | c.1377G>A p.L459= | Silent (SNP) | VAF 27/92 reads (29%) | catalogued as COSV99536892; called by muse, mutect2, varscan2
- ZNF366 | c.1950C>T p.T650= | Silent (SNP) | VAF 62/148 reads (42%) | catalogued as COSV100574264; called by muse, mutect2, varscan2
- ZNF560 | c.405C>T p.Y135= | Silent (SNP) | VAF 34/95 reads (36%) | catalogued as COSV100038626; called by muse, mutect2, varscan2
- AC073310.1 | n.808T>C | RNA (SNP) | VAF 27/112 reads (24%) | catalogued as rs1427977319; called by muse, mutect2, varscan2
- CSMD2 | c.*1C>A | 3'UTR (SNP) | VAF 26/86 reads (30%) | catalogued as COSV53963904, COSV99590051; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152446123 C>G | 3'Flank (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- IMPDH1 | chr7:128409480 T>A | 5'Flank (SNP) | VAF 35/152 reads (23%) | catalogued as COSV100118685; called by muse, mutect2, varscan2
- KCNK10 | c.38-7193G>C | Intron (SNP) | VAF 54/308 reads (18%) | catalogued as COSV100068355; called by muse, mutect2, varscan2
- LINC01098 | n.655G>T | RNA (SNP) | VAF 12/50 reads (24%) | catalogued as rs775712184; called by muse, mutect2, varscan2
- MIR133B | n.33G>T | RNA (SNP) | VAF 22/73 reads (30%) | called by muse, mutect2, varscan2
- MIR409 | n.67C>A | RNA (SNP) | VAF 20/117 reads (17%) | called by muse, mutect2, varscan2
- MIR517A | n.33G>A | RNA (SNP) | VAF 26/107 reads (24%) | catalogued as rs1358046432; called by muse, mutect2, varscan2
- RAPH1 | c.733-8355C>T | Intron (SNP) | VAF 24/94 reads (26%) | catalogued as rs1191763295, COSV100051514; called by muse, mutect2, varscan2
- SSPOP | n.14732C>T | RNA (SNP) | VAF 5/44 reads (11%) | catalogued as COSV100947423; called by muse, mutect2, varscan2
- TTN | c.10361-4978dup | Intron (INS) | VAF 16/146 reads (11%) | called by mutect2, pindel, varscan2
- VWA3B | c.*1G>T | 3'UTR (SNP) | VAF 10/32 reads (31%) | catalogued as rs757029021, COSV101417785; called by muse, mutect2, varscan2
- WNK1 | c.2140-2790G>C | Intron (SNP) | VAF 7/35 reads (20%) | catalogued as COSV100267428; called by muse, mutect2, varscan2
- ZBTB3 | c.-65T>C | 5'UTR (SNP) | VAF 14/60 reads (23%) | catalogued as COSV101188965; called by mutect2, varscan2
